Gene-level copy-number profile of tumor specimen CUPP-B38T-TTM1-A from CCG case CUPP-B38T, project CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma, endocervical type; Tissue or organ of origin: Unknown primary site; AJCC pathologic stage: Stage III; Age at diagnosis: 72.0 years (26,292 days).
Specimen CUPP-B38T-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1bb73c11-d4b2-46e9-a423-26ddce459e16.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CUPP-B38T-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,721 have no estimate.
https://portal.gdc.cancer.gov/files/928da450-3aa4-4c8b-979f-2d5420094248

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 87; copy number 1: 3,801; copy number 2: 53,860; copy number 3: 1,056; copy number 4: 22; copy number 5: 76.

Homozygous deletions (total copy number 0; autosomes only): 45 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,324,756–1,335,314, 2 genes (within-gene range 0–2): CPTP, TAS1R3.
- chr1:43,991,500–44,031,467, 1 gene (within-gene range 0–2): SLC6A9.
- chr4:958,887–986,895, 1 gene (within-gene range 0–1): DGKQ.
- chr4:1,793,293–1,808,872, 1 gene: FGFR3.
- chr5:139,644,460–139,683,882, 3 genes: AC113361.1, CXXC5, CXXC5-AS1.
- chr6:80,555,841–80,557,189, 1 gene: AL590824.1.
- chr7:56,805,336–56,808,148, 1 gene: CICP28.
- chr7:137,318,592–137,326,953, 1 gene (within-gene range 0–2): AC078842.2.
- chr8:143,603,210–143,618,048, 2 genes (within-gene range 0–2): PYCR3, GFUS.
- chr10:133,246,478–133,247,891, 2 genes: MIR202HG, MIR202.
- chr15:41,825,099–41,894,053, 7 genes (within-gene range 0–2): AC020659.2, JMJD7, JMJD7-PLA2G4B, PLA2G4B, SPTBN5, RNA5SP393, MIR4310.
- chr16:981,770–1,000,926, 2 genes: SOX8, AC009041.1.
- chr16:1,770,286–1,794,971, 6 genes (within-gene range 0–2): NME3, MRPS34, EME2, SPSB3, NUBP2, IGFALS.
- chr16:15,104,312–15,154,564, 5 genes (within-gene range 0–2): NPIPP1, PKD1P6-NPIPP1, PKD1P6, MIR6511B2, Y_RNA.
- chr17:4,897,771–4,934,438, 2 genes (within-gene range 0–2): CHRNE, C17orf107.
- chr21:13,525,599–13,545,185, 2 genes: SNX19P1, OR4K11P.
- chr21:44,978,832–44,979,274, 1 gene: AP001505.1.
- chr21:44,999,208–45,004,727, 1 gene: PICSAR.
- chr21:45,478,266–45,573,365, 2 genes (within-gene range 0–2): MIR6815, SLC19A1.
- chr22:41,922,032–41,926,806, 2 genes: TNFRSF13C, MIR378I.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 76 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,583,865–149,705,716, 6 genes, copy number 5 (within-gene range 1–5): PPIAL4C, LINC00869, AC242842.2, AC242842.1, RNVU1-30, FAM91A2P.
- chr7:38,239,580–38,350,022, 19 genes, copy number 5 (within-gene range 2–5): TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6, TRGV5P, TRGV5.
- chr14:22,040,594–22,486,296, 50 genes, copy number 5: TRAV20, TRAV21, AC245505.3, TRAV22, TRAV23DV6, TRDV1, TRAV24, TRAV25, TRAV26-1, TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52.
- chr14:22,547,506–22,552,156, 1 gene, copy number 5: TRAC.

Autosomal genes at a single copy (total copy number 1): 1,046. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
